Somatic mutation profile of tumor specimen TCGA-22-5474-01A (aliquot TCGA-22-5474-01A-01D-1632-08) from TCGA case TCGA-22-5474, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 74.7 years (27,271 days).
Specimen TCGA-22-5474-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34db7a94-9a83-423f-b9b2-9ac6d911c95d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-5474-11A (Solid Tissue Normal), aliquot TCGA-22-5474-11A-01D-1632-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f55e9eca-4716-421e-846d-e3ffc9842523

The open-access MAF lists 91 somatic variants for this specimen: 75 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 15, Nonsense Mutation 5, Frame Shift Del 3, Frame Shift Ins 2, Splice Site 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 21/80 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.701A>C p.Y234S | Missense Mutation (SNP) | VAF 28/45 reads (62%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.580A>G p.T194A | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.424); catalogued as COSV60625416; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3674A>G p.Y1225C | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV54450267; called by muse, mutect2, varscan2
- ANKRD17 | c.7492C>G p.Q2498E | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); catalogued as COSV58220715; called by muse, mutect2, varscan2
- ATF7IP | c.1288A>G p.M430V | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs769322964, COSV53771619; called by muse, mutect2, varscan2
- ATP1A4 | c.1121C>T p.T374M | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1188078056, COSV63626720; called by muse, mutect2, varscan2
- CA9 | c.416G>A p.S139N | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as rs746693979, COSV65675790; called by muse, mutect2, varscan2
- CALN1 | c.124C>T p.R42* (on ENST00000329008 / NM_001017440.3; = p.R84* on NM_031468.4) | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as rs1267060461, COSV61133555; called by muse, mutect2, varscan2
- CCDC60 | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV59544614; called by muse, mutect2, varscan2
- CCNB3 | c.269C>A p.S90Y | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.498); catalogued as COSV52074314, COSV52077631; called by muse, mutect2, varscan2
- CCNYL1 | c.745G>A p.D249N (on ENST00000295414 / NM_001330218.2; = p.D179N on NM_152523.2) | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.377); catalogued as COSV54940394; called by muse, mutect2, varscan2
- CDON | c.2570C>T p.T857I | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54998500; called by muse, mutect2, varscan2
- CFTR | c.3380G>C p.G1127A | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as CD141630, CM941982, COSV50040585, COSV50057922; called by muse, mutect2, varscan2
- CFTR | c.4367G>T p.S1456I | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.398); catalogued as COSV50057996; called by muse, mutect2
- COPS2 | c.463-1G>A p.X155_splice | Splice Site (SNP) | VAF 9/43 reads (21%) | catalogued as COSV54645451; called by muse, mutect2, varscan2
- CTNND1 | c.2353G>C p.V785L (on ENST00000399050 / NM_001085458.2; = p.V779L on NM_001331.3) | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV62383772; called by muse, mutect2
- CTR9 | c.2453C>T p.S818F | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as COSV63728716; called by mutect2, varscan2
- DDR1 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61321480; called by muse, mutect2, varscan2
- DNAH5 | c.5565C>G p.I1855M | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV54228401, COSV54233909, COSV54237916; called by muse, mutect2, varscan2
- DNAH5 | c.685C>T p.L229F | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV54228415; called by muse, mutect2, varscan2
- EMILIN1 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1278526194, COSV66694838; called by muse, mutect2, varscan2
- EPHA1 | c.2422G>A p.D808N | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747132712, COSV51970251; called by muse, mutect2, varscan2
- ERLEC1 | c.158C>G p.S53C | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as rs372793033, COSV51751960; called by muse, mutect2, varscan2
- EXPH5 | c.3257C>T p.S1086L | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as COSV56202964; called by muse, mutect2, varscan2
- FABP1 | c.67G>A p.G23S | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1242454555, COSV55558624; called by muse, mutect2, varscan2
- FHL2 | c.284A>G p.N95S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.048); catalogued as rs727505151, COSV59079657; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FSHR | c.113C>G p.T38R | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.416); catalogued as COSV58624565; called by muse, mutect2, varscan2
- GLB1L | c.1009G>C p.E337Q | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55476842; called by muse, mutect2, varscan2
- GRID2 | c.1092G>T p.Q364H | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.601); catalogued as COSV56211806; called by muse, mutect2, varscan2
- HTRA2 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV51208092; called by muse, mutect2, varscan2
- IFNA17 | c.268C>G p.L90V | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs1268775921, COSV69738169; called by muse, mutect2, varscan2
- IKBKB | c.1458C>G p.F486L | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV60597560; called by muse, mutect2, varscan2
- INHBA | c.90C>A p.S30R | Missense Mutation (SNP) | VAF 58/254 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as rs942081109, COSV54221946, COSV99638126; called by muse, varscan2
- INTS3 | c.1714G>C p.D572H | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV59677352, COSV59678048, COSV99056112; called by muse, mutect2, varscan2
- ITGA11 | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs753387408, COSV59878187; called by muse, mutect2, varscan2
- KIAA1109 | c.6524T>A p.M2175K | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV52675303; called by muse, mutect2, varscan2
- KIF24 | c.1105G>T p.D369Y | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100799062, COSV61455435, COSV61457655; called by muse, mutect2, varscan2
- KIF2C | c.2054C>G p.S685C | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV64764637; called by muse, mutect2, varscan2
- KIF2C | c.2103C>G p.I701M | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as COSV64764640; called by muse, mutect2, varscan2
- KRT4 | c.1316A>G p.Y439C | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53407586; called by muse, mutect2, varscan2
- KRT6A | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.434); catalogued as COSV58105408; called by muse, mutect2, varscan2
- LIMA1 | c.1417G>C p.E473Q | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV57965719; called by muse, mutect2
- LRP1 | c.8264G>A p.G2755D | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54513141; called by muse, mutect2, varscan2
- MED1 | c.4308C>G p.I1436M | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.605); catalogued as rs1367731315, COSV56125241; called by muse, mutect2, varscan2
- MED1 | c.4205C>G p.P1402R | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as COSV56125251; called by muse, mutect2, varscan2
- MED1 | c.3583C>T p.H1195Y | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV56125264; called by muse, mutect2, varscan2
- MRPS28 | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 14/45 reads (31%) | catalogued as COSV52562791, COSV52566114; called by muse, mutect2, varscan2
- MSANTD4 | c.841G>A p.G281S | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs1479414192, COSV57285913; called by muse, mutect2, varscan2
- NCOA2 | c.887G>A p.W296* | Nonsense Mutation (SNP) | VAF 47/153 reads (31%) | catalogued as COSV71764055; called by muse, mutect2, varscan2
- NOS1 | c.699G>A p.M233I | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV57613504, COSV57617746; called by muse, mutect2, varscan2
- NPFFR2 | c.1471C>G p.H491D | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.026); catalogued as COSV100440652, COSV58150250; called by muse, mutect2, varscan2
- OR4C11 | c.250C>T p.L84F | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs570575344, COSV56353511; called by muse, mutect2, varscan2
- OR5F1 | c.379T>C p.C127R | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53546711; called by muse, mutect2, varscan2
- PBX1 | c.982A>G p.T328A | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.146); catalogued as COSV63344074; called by muse, mutect2
- PCDHA8 | c.994G>C p.G332R | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV100970457; called by muse, mutect2, varscan2
- PCLO | c.1940G>T p.G647V | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV61638598, COSV61642972; called by muse, mutect2, varscan2
- RPL3L | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 35/74 reads (47%) | catalogued as COSV51906824; called by muse, mutect2, varscan2
- RYR1 | c.2167+2T>C p.X723_splice | Splice Site (SNP) | VAF 61/150 reads (41%) | catalogued as COSV62098851; called by muse, mutect2, varscan2
- SETX | c.516C>G p.I172M | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748037460, COSV56386462; called by muse, mutect2, varscan2
- SOX5 | c.1640G>A p.R547Q | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761424973, COSV58621509, COSV58631332; called by muse, mutect2, varscan2
- SPEF2 | c.3085C>T p.P1029S | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.647); catalogued as COSV61548675; called by muse, mutect2, varscan2
- TLR4 | c.1238C>G p.T413S (on ENST00000355622 / NM_138554.5; = p.T373S on NM_003266.4) | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV62923386; called by muse, mutect2
- TNS3 | c.4192A>G p.K1398E | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as rs536929378, COSV60791740; called by muse, mutect2, varscan2
- TRAPPC12 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs754550846, COSV60847908; called by muse, mutect2, varscan2
- TRIM25 | c.1727G>C p.R576P | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57544346, COSV57545313; called by muse, mutect2, varscan2
- UVRAG | c.1169G>T p.G390V | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62104750; called by muse, mutect2, varscan2
- ZBTB18 | c.1042G>T p.E348* | Nonsense Mutation (SNP) | VAF 25/51 reads (49%) | catalogued as COSV62396737; called by muse, mutect2, varscan2
- ZDHHC20 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.487); catalogued as rs1472706047, COSV57186263; called by muse, mutect2
- ZNF222 | c.1046G>T p.G349V | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV51826992; called by muse, mutect2, varscan2
- CLEC1B | c.246del p.Q82Hfs*4 | Frame Shift Del (DEL) | VAF 11/58 reads (19%) | called by mutect2, pindel, varscan2
- CTNND1 | c.813dup p.L272Sfs*14 | Frame Shift Ins (INS) | VAF 43/222 reads (19%) | called by mutect2, pindel, varscan2
- MYH4 | c.1928del p.K643Rfs*17 | Frame Shift Del (DEL) | VAF 25/63 reads (40%) | called by mutect2, pindel, varscan2
- SCN11A | c.4785del p.V1596Sfs*7 | Frame Shift Del (DEL) | VAF 27/92 reads (29%) | called by mutect2, pindel, varscan2
- USP15 | c.2127dup p.R710Tfs*14 (on ENST00000280377 / NM_001351159.2; = p.R681Tfs*14 on NM_006313.3 and 5 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 12/75 reads (16%) | called by mutect2, pindel, varscan2
- ADCY8 | c.1818G>A p.V606= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as COSV53910035; called by muse, mutect2, varscan2
- AHDC1 | c.618C>T p.D206= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV55939270; called by muse, mutect2, varscan2
- AMER3 | c.1152C>T p.D384= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs200882863, COSV58467148; called by muse, mutect2, varscan2
- ANKRD11 | c.1764G>A p.S588= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs762077340, COSV56362037; called by mutect2, varscan2
- ANO2 | c.1938G>T p.V646= (on ENST00000356134 / NM_001278597.3; = p.V650= on NM_001278596.3) | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV59025247; called by muse, mutect2, varscan2
- CYGB | c.288G>T p.L96= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV53150298; called by muse, mutect2, varscan2
- MMRN2 | c.1503G>T p.L501= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV100922652, COSV64400806; called by muse, mutect2, varscan2
- NUP210 | c.1362C>T p.I454= | Silent (SNP) | VAF 22/131 reads (17%) | catalogued as COSV54407009; called by muse, mutect2, varscan2
- OGDH | c.918C>A p.I306= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV56050734; called by muse, mutect2, varscan2
- OR4D2 | c.768C>T p.Y256= | Silent (SNP) | VAF 56/111 reads (50%) | catalogued as COSV73459776; called by muse, mutect2, varscan2
- PLCB4 | c.117C>T p.F39= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV53803439; called by muse, mutect2, varscan2
- PPP2R1A | c.87C>T p.L29= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV59044989; called by muse, mutect2, varscan2
- PRR14L | c.6033A>G p.S2011= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as COSV57884814; called by muse, mutect2, varscan2
- TYRO3 | c.1453C>A p.R485= | Silent (SNP) | VAF 23/128 reads (18%) | catalogued as rs776839937, COSV55480998, COSV55483604; called by muse, varscan2
- ZNF569 | c.606C>T p.I202= | Silent (SNP) | VAF 30/106 reads (28%) | catalogued as COSV57595795; called by muse, mutect2, varscan2
- MGA | c.4435-41C>T | Intron (SNP) | VAF 23/130 reads (18%) | catalogued as COSV54955085; called by muse, mutect2, varscan2
